Gene-level copy-number profile of tumor specimen TCGA-29-1704-02A from TCGA case TCGA-29-1704, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.6 years (22,511 days).
Specimen TCGA-29-1704-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c6577ae4-0596-4d37-b886-b756cf6fc80a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1704-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file.
https://portal.gdc.cancer.gov/files/1b5b29e2-2b36-4f76-b508-f05cf9278519

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 17,000; copy number 2: 31,014; copy number 3: 9,835; copy number 4: 1,562; copy number 5: 227; copy number 6: 71; copy number 7: 18.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:180,731,164–180,759,038, 1 gene (within-gene range 0–1): AC104803.1.
- chr5:97,504,663–97,923,497, 5 genes (within-gene range 0–1): LINC01340, MTCYBP40, AC112203.1, AC122697.1, LINC02234.
- chr5:102,753,981–103,033,031, 2 genes (within-gene range 0–2): PAM, EIF3KP1.
- chr5:123,344,890–123,423,592, 1 gene (within-gene range 0–1): CEP120.
- chr6:93,240,020–93,419,559, 1 gene (within-gene range 0–1): EPHA7.
- chr6:114,866,873–114,866,976, 1 gene: RNU6-475P.
- chr6:134,706,060–134,707,349, 1 gene: AL121970.1.
- chr8:18,391,282–18,401,218, 1 gene: NAT2.
- chr11:6,926,404–7,020,346, 2 genes (within-gene range 0–1): ZNF215, ZNF214.
- chr13:53,345,211–53,410,880, 1 gene (within-gene range 0–1): AL450423.1.
- chr18:79,340,258–79,529,325, 7 genes (within-gene range 0–1): AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 315 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 2–6): AC244205.1.
- chr2:88,857,161–89,268,506, 41 genes, copy number 6: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33.
- chr3:172,505,508–172,711,218, 6 genes, copy number 5 (within-gene range 3–5): TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2.
- chr4:2,741,648–2,930,076, 4 genes, copy number 5 (within-gene range 3–5): TNIP2, SH3BP2, ADD1, AL121750.1.
- chr7:27,412,164–28,180,795, 10 genes, copy number 5 (within-gene range 3–5): AC004009.2, EIF4HP1, PSMC1P2, AC073150.1, HIBADH, AC007130.1, TAX1BP1-AS1, TAX1BP1, JAZF1, AC004549.1.
- chr7:30,176,387–30,179,014, 1 gene, copy number 5: AC007036.1.
- chr8:84,828,573–84,864,907, 2 genes, copy number 5: AC009901.1, AC009901.2.
- chr8:123,002,560–123,165,173, 5 genes, copy number 5: AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3.
- chr8:133,668,420–134,713,049, 16 genes, copy number 5 (within-gene range 4–5): Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3.
- chr8:143,915,153–144,708,517, 60 genes, copy number 5 (within-gene range 3–5): PLEC, MIR661, PARP10, GRINA, SPATC1, SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1, SHARPIN, MAF1, WDR97, HGH1, TSSK5P, MROH1, BOP1, MIR7112, SCX, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82, ARHGAP39, AC084125.3, Metazoa_SRP, AF186192.1, AF186192.2.
- chr9:14,475–5,129,948, 81 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:129,321,016–129,380,470, 5 genes, copy number 5: C9orf106, AL353803.5, LINC01503, RN7SL159P, AL353803.3.
- chr11:73,675,638–74,485,742, 31 genes, copy number 5–7 (within-gene range 3–7): RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3.
- chr19:19,033,575–19,546,659, 24 genes, copy number 5 (within-gene range 3–5): ARMC6, SLC25A42, TMEM161A, MEF2B, BORCS8-MEF2B, BORCS8, RFXANK, NR2C2AP, NCAN, RNU6-1028P, AC138430.1, HAPLN4, AC138430.2, TM6SF2, SUGP1, MAU2, GATAD2A, AC092067.1, MIR640, TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2.
- chr20:31,404,845–31,952,046, 27 genes, copy number 6 (within-gene range 2–6): DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1.
- chr20:31,970,181–31,970,831, 1 gene, copy number 6: AL031658.2.

Autosomal genes at a single copy (total copy number 1): 16,987. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
